TCGA case TCGA-29-1704 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e7f1c74-7cb3-43c0-b07c-bf69b780053f

Demographics
Sex at birth: female; Race: white; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,511 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,587 days (4.3 years).
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 169 days; Number of cycles: 6; Treatment dose: 4 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 169 days; Number of cycles: 6; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 642 days (1.8 years); Days to treatment end: 775 days (2.1 years); Number of cycles: 6; Treatment dose: 485 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 642 days (1.8 years); Days to treatment end: 775 days (2.1 years); Number of cycles: 6; Treatment dose: 230 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 930 days (2.5 years); Days to treatment end: 964 days (2.6 years); Treatment dose: 3,500 cGy; Number of fractions: 20; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,188 days (3.3 years); Days to treatment end: 1,300 days (3.6 years); Number of cycles: 5; Treatment dose: 70 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,566 days (4.3 years); Days to treatment end: 1,587 days (4.3 years); Treatment dose: 1,100 mg; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,566 days (4.3 years); Days to treatment end: 1,587 days (4.3 years); Number of cycles: 3; Treatment dose: 70 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 63.2 years (23,079 days); Days to diagnosis: 568 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 608 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (4 entries)
- Day 568 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 568 days (1.6 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,587 days (4.3 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1704-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-29-1704-01B-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-29-1704-01B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-29-1704-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-29-1704-02A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-29-1704-02A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-29-1704-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,587 days; disease-specific survival: no event (censored), 1,587 days; disease-free interval: event (new tumor event after initially disease-free), 568 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 568 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-29-1704-01): tumor purity 0.74, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).
